Surgical pathology report (de-identified scan), TCGA case TCGA-06-0171, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0171-02A (Recurrent Tumor).

PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX: M DOB:

SURGERY DATE:

PATIENT PHONE NO.:

RECEIVE DATE:

PHYSICIAN:

COPY TO:

UPDATED REPORT - SEE SPECIAL STAIN REPORT

PATHOLOGICAL DIAGNOSIS:

BRAIN, RIGHT FRONTAL, EXCISION: EXTENSIVE COAGULATION NECROSIS,
PARENCHYMAL REACTIVE CHANGES, VASCULOPATHY, AND SMALL FOCI OF ATYPICAL
GLIAL PROLIFERATION.

SEE COMMENT.

Operation/Specimen: Recurrent right frontal brain tumor.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY:

SPECIMEN: Recurrent right frontal brain tumor.
FIXATIVE: Formalin.
GENERAL: A 5.5 x 4 x 1.5 cm. aggregate of gray-tan soft brain
tissue admixed with sanguinous clot. No discrete
nodules are identified.
SECTION: 1-5 - submitted in toto.

ICD - 0-3 - Recurrent
tumor, NOS 8000/1
Site: brain, frontal lobe C71.1

h
2/15

COMMENT: The bulk of the specimen is brain parenchyma with rarefaction, prominent glial reactive changes, extensive areas of coagulation necrosis, and widespread vasculopathy. In addition, there are a couple of small zones in which cellularity and nuclear atypia are prominent and suggestive of neoplasm. However, a reactive change with post-radiation atypia may not be completely excluded.

SPECIAL STAIN REPORT: Immunoperoxidase methods for GFAP and MIB-1 were performed on sections from blocks 3 and 4.

The GFAP demonstrates that the great majority of astrocytes, although atypical, have a reactive phenotype. There is mitotic activity that by its distribution is most likely in lymphocytic/phagocytic cells. Although isolated tumor cells cannot be ruled out, the process overall does not appear neoplastic.

TISSUE COMMITTEE CODE:

Requested by:

Source: NCI Genomic Data Commons file ac7c8e6b-fe55-43a3-8b26-b108342c37ea (TCGA-06-0171.67747995-B764-412D-B8BE-E78094120153.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).